Somatic mutation profile of tumor specimen C3N-00656-54 (aliquot CPT0438050002) from CPTAC case C3N-00656, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 62.0 years (22,663 days).
Specimen C3N-00656-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 158b2bd8-fe1e-4bbf-827e-0b2e69ddf889.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00656-50 (Buccal Cell Normal), aliquot CPT0435090001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a642b8ee-8a64-4f63-812e-666d1ff181a6

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, Nonsense Mutation 1, RNA 1, 5'UTR 1, Splice Site 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSF3R | c.2353A>T p.K785* | Nonsense Mutation (SNP) | VAF 12/138 reads (9%) | catalogued as COSV58965511, COSV58973172; called by muse, mutect2
- DAGLB | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.078); catalogued as rs201911372; called by muse, mutect2, varscan2
- DPF2 | c.884G>C p.C295S | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52889333; called by muse, mutect2, varscan2
- MYF6 | c.408C>G p.S136R | Missense Mutation (SNP) | VAF 159/301 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775330322, COSV104391219; called by muse, mutect2, varscan2
- ABCA5 | c.1675_1680del p.G559_I560del | In Frame Del (DEL) | VAF 16/80 reads (20%) | called by mutect2, pindel, varscan2
- BBS2 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 106/236 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- FAM13C | c.929A>T p.E310V | Missense Mutation (SNP) | VAF 66/128 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCER1A | c.119G>A p.R40K | Missense Mutation (SNP) | VAF 82/169 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- NAALADL2 | c.1232A>G p.N411S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0); called by mutect2, varscan2
- NCOR1 | c.909+2T>A p.X303_splice | Splice Site (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- STAG2 | c.3070_3071dup p.F1025Sfs*3 | Frame Shift Ins (INS) | VAF 24/92 reads (26%) | called by mutect2, pindel, varscan2
- AASS | c.1359T>C p.G453= | Silent (SNP) | VAF 19/228 reads (8%) | catalogued as rs778445624; called by muse, mutect2
- FAM47A | c.222C>T p.D74= | Silent (SNP) | VAF 60/125 reads (48%) | catalogued as COSV60495771; called by muse, mutect2, varscan2
- IDI1 | c.84T>C p.C28= | Silent (SNP) | VAF 58/354 reads (16%) | catalogued as rs562653913; called by muse, mutect2, varscan2
- NOC4L | c.924C>G p.A308= | Silent (SNP) | VAF 17/78 reads (22%) | called by muse, mutect2, varscan2
- FKBP15 | c.-2C>T | 5'UTR (SNP) | VAF 16/252 reads (6%) | called by muse, mutect2
- LRRC37A5P | n.392T>G | RNA (SNP) | VAF 173/377 reads (46%) | called by muse, mutect2, varscan2
